Surgical pathology report (de-identified scan), TCGA case TCGA-92-8064, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - St. Louis, specimen TCGA-92-8064-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

Accession #:
Taken:
Received:
Accessioned:
Reported:

DIAGNOSIS:

LUNG, RIGHT UPPER LOBE, EXCISION - EPIDERMOID CARCINOMA

SOFT TISSUE, "TUMOR," EXCISION - EPIDERMOID CARCINOMA

LUNG, RIGHT MIDDLE LOBE, WEDGE EXCISION - NO EVIDENCE OF MALIGNANCY

LUNG, "NORMAL," EXCISION - NO EVIDENCE OF MALIGNANCY

LYMPH NODE, PERIBRONCHIAL, EXCISION - NO HISTOPATHOLOGIC ABNORMALITY (2/2)

LYMPH NODE, LEVEL 4R, EXCISIONAL BIOPSY - NO HISTOPATHOLOGIC ABNORMALITY (5/5)

LYMPH NODE, LEVEL 7, EXCISIONAL BIOPSY - NO HISTOPATHOLOGIC ABNORMALITY (3/3)

LYMPH NODE, LEVEL 9, EXCISIONAL BIOPSY - NO HISTOPATHOLOGIC ABNORMALITY (2/2)

LYMPH NODE, LEVEL 10R, EXCISIONAL BIOPSY - NO HISTOPATHOLOGIC ABNORMALITY (1/1)

Intraoperative Consultation:

An intraoperative microscopic consultation was obtained and interpreted as: "Brought to the frozen section area is a specimen labeled 'right upper lobe,' consisting of a lobe of lung measuring 18 x 12 x 3 cm and weighing 174 grams. The pleural surface is smooth without puckering. The staple line over the area adjacent to the right middle lobe is removed and the underlying parenchyma inked blue. The lung is sectioned to show a tan-yellow, focally necrotic tumor, measuring 5.1 x 3.8 x 3.7 cm, approximately 1 mm from the inked margin. A section of tumor in relation to the nearest margin is frozen as FS1. The tumor (2.5 grams) and normal tissue taken for study. Tumor and normal tissue also taken for studies. Rest for permanent sections," by

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

"Also brought to the frozen section area is a specimen labeled 'bronchial sleeve,' consisting of a segment of bronchus measuring 1.5 cm in length, 1.6 cm in diameter and marked with a long and short suture. The marked margins are shaved and frozen as FS2A (short suture, proximal margin) and FS2B (long suture, distal margin). Rest for permanent sections," by [REDACTED]

FS1: Right middle lobe, tumor in relation to margin

- "Non-small cell carcinoma, approximately 1 mm from the inked margin," by [REDACTED]

FS2A: Proximal bronchial margin

- "No evidence of malignancy," by [REDACTED]

FS2B: Distal bronchial margin

- "No evidence of malignancy," by [REDACTED]

Microscopic Description and Comment:

Sections of the right upper lobe show poorly differentiated, non-keratinizing, epidermoid carcinoma with large vessel invasion. The material from the right middle lobe and "normal" lung show mild emphysema with no evidence of tumor. The bronchial margin and all sampled lymph nodes are free of tumor [REDACTED]

History:

The patient is a [REDACTED] of unstated race, with a right lung mass. Operative procedure: Thoracotomy and right upper lobectomy.

Specimen(s) Received:

A: LYMPH NODE, 10R
B: LYMPH NODE, LEVEL 9
C: LYMPH NODE, LEVEL 7
D: LUNG, RIGHT UPPER LOBE
E: BRONCHIAL SLEEVE
F: LYMPH NODE, LEVEL 7B
G: LYMPH NODE, LEVEL 9B
H: TUMOR
I: LUNG, RIGHT MIDDLE LOBE WEDGE
J: NORMAL LUNG
K: LYMPH NODE, 4R #1
L: LYMPH NODE, 4R #2
M: LYMPH NODE, 4R #3

Gross Description:

The specimens are received in 13 formalin-filled containers, each labeled with the patient's name, [REDACTED]. The first container is labeled "10R." It holds a single dark brown-tan putative lymph node that measures 1.2 x 0.7 x 0.5 cm. Bisected. Labeled A. Jar 0.

The second container is labeled, "level 9." It holds a piece of yellow-tan fibroadipose tissue attached to black-tan putative lymph node tissue that measures 0.8 x 0.7 x 0.3 cm. Labeled B. Jar 0.

The third container is labeled "level 7." It holds two black-tan putative lymph nodes. The larger measures 2.5 x 1.1 x 0.4 cm and the smaller 0.6 x 0.6 x 0.3 cm. Labeled C1 - larger lymph node, bisected; C2 - smaller lymph node. Jar 0.

The fourth container is labeled "RUL, FS1/X." It holds a green tissue cassette labeled "FS1," that contains two gray-tan pieces of lung parenchyma that together measure 2.5 x 2.3 x 0.4 cm. A white-tan nodular lesion, measuring

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

approximately 1.0 cm in greatest dimension, approximates the blue inked resection margin in the larger tissue fragment. Labeled D1 (FS1). Also in the container is a lobectomy specimen with weight and dimensions consistent with the intraoperative consultation. There are two staple lines measuring 8.8 and 4.5 cm respectively. The pleural surface is wrinkled, pink-tan and shows areas of black-tan mottling. The specimen has been previously sectioned to expose spongy brown-tan lung parenchyma and a lobulated, non-encapsulated, well circumscribed, firm, white-tan lesion abutting the main stem bronchus of the lobe. The resection margin has been previously inked blue. There are numerous defects in the tumor, where tissue was taken for tumor bank, the largest of which measures 2.5 cm in greatest dimension. The pleura overlying the tumor, near the mainstem bronchus has been disrupted, making it difficult to assess the pleura for invasion by the tumor. The tumor appears to invade the main stem bronchus, and a plug of tumor is within the lumen of the airway at the margin of resection. The blood vessel at the resection margin appears to be free of tumor. At least one black-tan putative peribronchial lymph node, measuring 1.3 cm in greatest dimension, is identified. The tumor is further sectioned to show that it encases peribronchial blood vessels. The remainder of the lung parenchyma shows no localizing lesions. Labeled D2 - vascular resection margin and bronchial resection margin with luminal tumor plug; D3 - peribronchial lymph node; D4 and D5 - tumor in relation to residual blue inked resection margin; D6 - tumor encasing peribronchial blood vessel; D7 - tumor in relation to lung parenchyma; D8 - uninvolved lung parenchyma and pleura. Jar 2.

The fifth container is labeled "long stitch - distal margin, short stitch - proximal margin - proximal sleeve, FS2A, 2B/X." It holds two green specimen cassettes and a "C-shaped" piece of pink-tan, cartilaginous bronchial tissue. The first tissue cassette is labeled "FS2A," and it holds a yellow-tan ring of cartilage and bronchial wall that measures 2.0 x 1.4 x 0.3 cm. Labeled E1 (FS2A). The second tissue cassette is labeled, "FS2B" and it holds a C-shaped piece of yellow-tan bronchial wall that measures 1.7 x 1.1 x 0.2 cm. Labeled E2 (FS2B). The remaining portion of bronchial wall in the container measures 2.3 x 1.3 x 1.1 cm. The mucosal lining is pink-tan and unremarkable. Trisected. Labeled E3 (X2). Jar 0.

The sixth container is labeled "level 7B." It holds a single black-tan putative lymph nodes that measures 0.9 x 0.6 x 0.4 cm. Bisected. Labeled F. Jar 0.

The seventh container is labeled, "level 9B." It holds two yellow-tan to black-tan pieces of fibroadipose tissue that measure 0.5 x 0.5 x 0.2 cm in aggregate. Labeled G. Jar 0.

The eighth container is additionally labeled "tumor." It holds two rubbery white-tan soft tissue fragments that measure 1.1 x 0.5 x 0.5 cm in aggregate. Attached to these fragments is a 2.6 x 0.7 x 0.5 cm portion of dark red-brown clot. Labeled H. Jar 0.

The ninth container is labeled "right middle lobe wedge." It holds a 7.7 gram wedge excision specimen of lung that measures 8.2 x 2.5 x 2.1 cm, with two staple lines that measure 7.7 and 7.2 cm respectively. The pleural surface is pink-tan, shiny and smooth with a 3.2 x 1.6 cm area of dark red-brown hemorrhage adjacent to one of the staple lines. No masses or nodules are palpated within the specimen. The staple lines are excised and the underlying parenchyma inked blue. The specimen is sectioned to show spongy, pink-tan lung parenchyma with focal subpleural hemorrhage. No localizing lesions are noted. Labeled I.

The tenth container is labeled "normal lung." It holds a 1.8 gram wedge excision of lung that measures 5.4 x 1.7 x 0.8 cm with a 4.5 cm staple line. The pleural surface is shiny, pink-tan and smooth with no areas of puckering noted. Sectioned to show spongy, pink-tan lung parenchyma with no localizing lesion. Labeled J. Jar 1.

The 11th container is labeled "4R#1." It holds two putative black-tan lymph nodes. The larger measures 1.7 x 0.9 x 0.8 cm, the smaller 1.5 x 0.7 x 0.6 cm. Labeled K1 - larger lymph node, trisected; A2 - smaller lymph node, bisected. Jar 0.

The 12th container is labeled "4R#2." It holds a lobulated piece of gray-tan tissue containing putative lymph nodes that measure 1.5 x 1.2 x 0.7 cm. Bisected. Labeled L. Jar 1.

The 13th container is labeled "4R#3." It holds two gray-tan to black-tan pieces of fibroadipose tissue containing putative lymph nodes that measure 1.8 x 1.2 x 0.6 and 1.5 x 1.3 x 0.6 cm, respectively. The second tissue fragment contains a putative lymph node measuring 1.3 cm in greatest dimension. Labeled M1 - larger tissue fragment; M2 - smaller tissue fragment with putative lymph node, bisected. Jar 0.

[page 4 of 4]
SYNOPSIS

HISTOPATHOLOGIC TYPE

The histologic classification of the tumor is epidermoid carcinoma, non-keratinizing

HISTOLOGIC GRADE

The grade of the tumor is poorly differentiated

TUMOR SIZE

The maximum dimension of the tumor is 5.1 cm

VASCULAR INVASION

Vascular invasion by tumor is present, microscopic

PLEURAL INVOLVEMENT

Pleural involvement is not evaluable

SAMPLED SPECIMEN MARGINS

The sampled surgical margins are uninvolved by tumor

PRIMARY TUMOR

T2b

REGIONAL LYMPH NODES

The total number of metastatically-involved lymph nodes is 13

N0

DISTANT METASTASIS

MX

Source: NCI Genomic Data Commons file f3ff96ea-7994-460e-a209-aa2706197e53 (TCGA-92-8064.38C3C16A-1A81-4812-9931-B5FB4B00615E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).